Somatic mutation profile of tumor specimen 0DCS59 from CCDI case PBBMKI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Central neurocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 18.8 years (6,863 days).
Specimen 0DCS59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3045aa61-abea-4376-8511-15465122299d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCS5C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0348af6e-71cf-4dc6-a44d-4f25807d3124

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1LI2 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 418/888 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.883); catalogued as COSV50754639; called by muse, mutect2, varscan2
- MACF1 | c.12872C>T p.A4291V (on ENST00000372915; = p.A2224V on NM_012090.5) | Missense Mutation (SNP) | VAF 427/1074 reads (40%) | catalogued as rs573837366, COSV57104402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC18A1 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 536/1148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs140046639; called by muse, mutect2, varscan2
- TENT5B | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 155/563 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs146612874; called by muse, mutect2, varscan2
- ENOSF1 | c.577A>G p.M193V (on ENST00000340116 / NM_001354066.2; = p.M145V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- EXOC2 | c.2470G>A p.V824I | Missense Mutation (SNP) | VAF 572/1171 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- GLYATL3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 39/698 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- GYPA | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 26/1123 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PPBP | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 169/1339 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ROBO1 | c.2839G>C p.V947L | Missense Mutation (SNP) | VAF 518/1265 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ULK3 | c.470-21_470-7del | Splice Region (DEL) | VAF 102/404 reads (25%) | called by mutect2, varscan2
- CHRNA9 | c.561C>T p.N187= | Silent (SNP) | VAF 46/1006 reads (5%) | catalogued as rs577497723; called by muse, mutect2
- PRDM7 | c.408G>A p.T136= | Silent (SNP) | VAF 120/792 reads (15%) | catalogued as rs770201192; called by muse, mutect2, varscan2
- IDH3G | c.233+98A>G | Intron (SNP) | VAF 12/12 reads (100%) | called by mutect2, varscan2
- KLK15 | c.481+27G>A | Intron (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
